Somatic mutation profile of tumor specimen MMRF_2789_1_BM_CD138pos (aliquot MMRF_2789_1_BM_CD138pos_T1_KHS5U_L15732) from MMRF case MMRF_2789, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2789_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19d3a868-1a97-4766-ba60-bbf899fead78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2789_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2789_1_PB_WBC_C3_KHS5U_L15776; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb9bafef-9b76-4625-ab2e-d06b20ebca8b

The open-access MAF lists 107 somatic variants for this specimen: 43 protein-altering or splice-affecting, 9 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 28, Intron 19, Silent 9, 5'UTR 4, RNA 3, Frame Shift Ins 2, Splice Site 2, Nonsense Mutation 2, Frame Shift Del 1, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- ADAD1 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.11); catalogued as rs1204070053; called by muse, mutect2, varscan2
- AGTPBP1 | c.3256C>T p.R1086C (on ENST00000357081 / NM_001330701.2; = p.R1046C on NM_015239.2) | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV61270545; called by muse, varscan2
- CDON | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as rs751107295, COSV54995037; called by muse, mutect2, varscan2
- EHD1 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 99/188 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as COSV57734678; called by muse, mutect2, varscan2
- FADS3 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs1288709642; called by muse, mutect2, varscan2
- GPKOW | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 54/59 reads (92%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs782802093, COSV50242104; called by muse, mutect2, varscan2
- IGHJ5 | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 29/29 reads (100%) | PolyPhen benign (0.034); catalogued as rs147551384; called by muse, varscan2
- IGHJ6 | c.55T>A p.S19T | Missense Mutation (SNP) | VAF 23/28 reads (82%) | PolyPhen probably damaging (0.986); catalogued as rs111729691; called by muse, varscan2
- IGHV2-70 | c.313A>T p.N105Y | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs377238058; called by muse, varscan2
- IGKV3-20 | c.163G>C p.A55P | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.864); catalogued as rs534391210; called by muse, mutect2, varscan2
- IGLV5-45 | c.342C>G p.Y114* | Nonsense Mutation (SNP) | VAF 97/256 reads (38%) | catalogued as rs189370797; called by muse, mutect2, varscan2
- IQCA1 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs776560283, COSV54505247; called by muse, mutect2, varscan2
- LRP2 | c.9221C>T p.T3074M | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755568696; called by muse, mutect2, varscan2
- TAZ | c.239-3T>A | Splice Region (SNP) | VAF 84/90 reads (93%) | catalogued as rs1557191562; called by muse, mutect2, varscan2
- TMCO1 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV100903196; called by muse, mutect2
- TMOD3 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs765953100; called by muse, mutect2, varscan2
- TRPS1 | c.1000C>T p.R334C (on ENST00000220888 / NM_001330599.2; = p.R347C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs780212915, COSV55251565, COSV55256742; called by muse, mutect2, varscan2
- UBR4 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.885); catalogued as rs373897497; called by muse, mutect2, varscan2
- UGT2B10 | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.21); catalogued as COSV55325055; called by muse, mutect2, varscan2
- WDR36 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1367754053; called by muse, mutect2
- ZBTB39 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as rs370004970; called by muse, mutect2, varscan2
- ABCA12 | c.1529A>T p.N510I (on ENST00000272895 / NM_173076.3; = p.N192I on NM_015657.3) | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.924); called by muse, mutect2
- ACTR8 | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ANO5 | c.1801-1G>T p.X601_splice | Splice Site (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- CCDC178 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- CCDC90B | c.763T>C p.*255Qext*2 | Nonstop Mutation (SNP) | VAF 10/291 reads (3%) | called by muse, mutect2
- CPB1 | c.355T>G p.Y119D | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.14228G>C p.G4743A | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FSIP2 | c.11535C>A p.H3845Q | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- GP2 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- H3C3 | c.96_102del p.T33Afs*2 | Frame Shift Del (DEL) | VAF 81/176 reads (46%) | called by mutect2, pindel, varscan2
- LIN9 | c.1204G>C p.D402H (on ENST00000366808 / NM_001270410.2; = p.D347H on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MPPED2 | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NXF1 | c.357G>T p.W119C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAQR3 | c.90_93dup p.T32Vfs*38 | Frame Shift Ins (INS) | VAF 36/83 reads (43%) | called by mutect2, pindel, varscan2
- PHYH | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- RICTOR | c.3902A>T p.Q1301L | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RYR2 | c.10231-2A>G p.X3411_splice | Splice Site (SNP) | VAF 35/42 reads (83%) | called by muse, mutect2, varscan2
- SNX19 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); called by muse, mutect2
- TENT5C | c.507dup p.V170Cfs*9 | Frame Shift Ins (INS) | VAF 18/104 reads (17%) | called by mutect2, pindel, varscan2
- TRPM8 | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TTN | c.99071T>C p.L33024P (on ENST00000591111; = p.L25600P on NM_003319.4) | Missense Mutation (SNP) | VAF 58/123 reads (47%) | PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CACNA1C | c.4614G>A p.V1538= | Silent (SNP) | VAF 63/140 reads (45%) | called by muse, mutect2, varscan2
- CCDC178 | c.1350G>T p.T450= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- KBTBD13 | c.846G>A p.A282= | Silent (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- KLHL35 | c.385C>T p.L129= | Silent (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- NMUR1 | c.30C>T p.V10= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100531922; called by muse, mutect2, varscan2
- PLIN4 | c.2154C>T p.T718= (on ENST00000301286; = p.T733= on NM_001367868.2) | Silent (SNP) | VAF 120/427 reads (28%) | catalogued as rs749022342; called by muse, varscan2
- RNF227 | c.567G>A p.T189= | Silent (SNP) | VAF 17/208 reads (8%) | called by muse, mutect2
- UNC5CL | c.504C>A p.P168= | Silent (SNP) | VAF 63/158 reads (40%) | called by muse, mutect2, varscan2
- ZP4 | c.927G>A p.E309= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- AC067904.2 | n.899A>T | RNA (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- ACIN1 | c.2298-1594G>C | Intron (SNP) | VAF 31/195 reads (16%) | called by muse, mutect2, varscan2
- ARRDC4 | c.-43G>A | 5'UTR (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- ATP5F1E | c.*3+221C>T | Intron (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- B3GAT3 | c.910-86A>G | Intron (SNP) | VAF 20/228 reads (9%) | called by muse, mutect2
- BHLHE40 | c.150+75C>T | Intron (SNP) | VAF 185/286 reads (65%) | called by muse, mutect2, varscan2
- BHLHE41 | c.*815C>G | 3'UTR (SNP) | VAF 50/84 reads (60%) | called by muse, mutect2, varscan2
- CCDC141 | c.1899+978T>C | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- CD48 | c.385+1152T>A | Intron (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- CDH6 | c.*5273A>G | 3'UTR (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- CDHR1 | c.*966A>T | 3'UTR (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- CFB | c.1169-17T>C | Intron (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- COMT | c.615+115G>A | Intron (SNP) | VAF 40/72 reads (56%) | catalogued as rs769380356; called by muse, mutect2, varscan2
- COPS8 | c.*1994T>A | 3'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- CRTC3 | c.*900A>G | 3'UTR (SNP) | VAF 24/264 reads (9%) | catalogued as rs1291318367; called by muse, mutect2
- CSTA | c.*199T>A | 3'UTR (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- DENND5B | c.*395T>A | 3'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- DNAJB9 | c.*517T>A | 3'UTR (SNP) | VAF 46/87 reads (53%) | called by muse, mutect2, varscan2
- DOCK5 | c.*2870dup | 3'UTR (INS) | VAF 25/55 reads (45%) | catalogued as rs1252941833; called by mutect2, varscan2
- ERMP1 | c.*498G>A | 3'UTR (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- FGFR1 | c.1553-94G>A | Intron (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- GDA | c.*1012A>G | 3'UTR (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- HMGA2 | c.249+3615G>A | Intron (SNP) | VAF 20/137 reads (15%) | catalogued as rs868316048; called by muse, mutect2, varscan2
- HNRNPA3 | c.644-31T>C | Intron (SNP) | VAF 30/240 reads (13%) | called by muse, mutect2, varscan2
- IGHV1-2 | c.-26A>C | 5'UTR (SNP) | VAF 43/51 reads (84%) | catalogued as rs782632396; called by muse, mutect2, varscan2
- LHFPL3 | c.*301G>C | 3'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- LIN54 | c.*2757G>A | 3'UTR (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- LUZP2 | c.*1454G>A | 3'UTR (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2
- MANEA | c.*2000G>A | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- MCF2L2 | c.1863-170A>T | Intron (SNP) | VAF 27/525 reads (5%) | called by muse, mutect2
- MIB1 | c.*4281T>A | 3'UTR (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- MON1B | c.*895C>T | 3'UTR (SNP) | VAF 59/128 reads (46%) | called by muse, mutect2, varscan2
- MYO1E | c.-55C>T | 5'UTR (SNP) | VAF 54/112 reads (48%) | catalogued as COSV99893901; called by muse, varscan2
- NCKAP5 | c.341+6510C>A | Intron (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- NLGN4X | c.*1888C>A | 3'UTR (SNP) | VAF 21/24 reads (88%) | called by muse, mutect2, varscan2
- NOX4 | chr11:89491392 G>A | 5'Flank (SNP) | VAF 5/56 reads (9%) | catalogued as rs1328277704; called by muse, mutect2, varscan2
- OR4C4P | n.275G>A | RNA (SNP) | VAF 24/59 reads (41%) | catalogued as rs1318297925; called by muse, varscan2
- PACRGL | c.*56+1886T>G | Intron (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- PAICS | c.*95G>T | 3'UTR (SNP) | VAF 72/141 reads (51%) | called by muse, mutect2, varscan2
- PGRMC1 | c.*943T>C | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- PJA2 | c.*2381G>T | 3'UTR (SNP) | VAF 34/66 reads (52%) | catalogued as COSV100754541; called by muse, mutect2, varscan2
- RAB11FIP5 | c.432-75C>T | Intron (SNP) | VAF 137/244 reads (56%) | called by muse, mutect2, varscan2
- RALGAPA2 | c.5495+1175G>C | Intron (SNP) | VAF 5/106 reads (5%) | called by muse, mutect2
- RPL28 | c.*1134T>G | 3'UTR (SNP) | VAF 101/198 reads (51%) | called by muse, mutect2, varscan2
- SHISA9 | c.563+6443C>A | Intron (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2, varscan2
- SLC13A4 | c.-605G>A | 5'UTR (SNP) | VAF 32/81 reads (40%) | catalogued as rs911332918; called by muse, mutect2, varscan2
- SLC22A2 | c.1064+700G>A | Intron (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- SLC66A1 | c.*401G>A | 3'UTR (SNP) | VAF 20/42 reads (48%) | catalogued as rs771042573; called by muse, mutect2, varscan2
- STXBP5L | c.*993G>A | 3'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- SYNE1 | c.4461+225T>A | Intron (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- TAS1R3 | c.*698T>C | 3'UTR (SNP) | VAF 56/118 reads (47%) | called by muse, mutect2, varscan2
- TENT4A | c.*309A>G | 3'UTR (SNP) | VAF 68/140 reads (49%) | called by muse, mutect2, varscan2
- TUBA8 | c.*579G>A | 3'UTR (SNP) | VAF 59/126 reads (47%) | called by muse, mutect2, varscan2
- TXLNGY | n.5878C>T | RNA (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- ZSWIM5 | c.*1633G>A | 3'UTR (SNP) | VAF 89/201 reads (44%) | called by muse, mutect2, varscan2
